Somatic mutation profile of tumor specimen C3N-00511-03 (aliquot CPT0078250006) from CPTAC case C3N-00511, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 45.1 years (16,455 days).
Specimen C3N-00511-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a712226-f304-4c41-8a39-9fac11274b43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00511-31 (Blood Derived Normal), aliquot CPT0078310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea214fbd-d27b-4aa6-bbd5-677af092a2c5

The open-access MAF lists 57 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Intron 3, Splice Site 3, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 71/292 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 84/353 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD35 | c.1706G>A p.G569E | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs1553739222, COSV100841784, COSV62911158; called by muse, mutect2, varscan2
- ASPM | c.8379G>A p.M2793I | Missense Mutation (SNP) | VAF 108/737 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs376057172; called by muse, mutect2, varscan2
- ATP6V1A | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759887224, COSV56363383; called by muse, mutect2, varscan2
- C4orf54 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs753181667; called by muse, mutect2
- CADPS | c.2444C>T p.S815L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV51901891; called by muse, mutect2
- CHST15 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1338359559; called by muse, mutect2, varscan2
- CPXM2 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as rs762600262, COSV53860503; called by muse, mutect2, varscan2
- DENND2A | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs766779073, COSV52050018; called by muse, mutect2, varscan2
- DOCK2 | c.3821G>A p.R1274Q | Missense Mutation (SNP) | VAF 53/256 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.711); catalogued as rs145262338, COSV99915170; called by muse, mutect2, varscan2
- DSCAM | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747625181, COSV68634704; called by muse, mutect2, varscan2
- EGR1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767122422; called by muse, mutect2, varscan2
- GALNT6 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62542092; called by muse, mutect2, varscan2
- GPR26 | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 50/254 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.047); catalogued as rs775340633; called by muse, mutect2, varscan2
- MAGEB17 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1446914265, COSV61556834; called by muse, mutect2, varscan2
- NCKAP1L | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs370847426; called by muse, mutect2, varscan2
- NID1 | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 74/375 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs536352898, COSV51615314; called by muse, mutect2, varscan2
- PCDHGA6 | c.2227G>A p.V743M | Missense Mutation (SNP) | VAF 89/478 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.043); catalogued as rs1211342702, COSV53899875; called by muse, mutect2, varscan2
- POU2F1 | c.992C>G p.A331G (on ENST00000541643 / NM_001365848.1; = p.A354G on NM_002697.4) | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54823646; called by muse, mutect2, varscan2
- PSG8 | c.430C>T p.L144= | Splice Region (SNP) | VAF 28/127 reads (22%) | catalogued as rs1466865677, COSV60610769; called by muse, mutect2, varscan2
- SAR1A | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV64698139; called by muse, mutect2, varscan2
- TEAD2 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 67/361 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV60874074; called by muse, mutect2, varscan2
- TMEM132A | c.2629C>T p.R877C (on ENST00000453848 / NM_178031.3; = p.R878C on NM_017870.4) | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1314490080, COSV50019253; called by muse, mutect2, varscan2
- VPS13B | c.2653G>C p.D885H | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); catalogued as COSV62160790; called by muse, mutect2, varscan2
- CLDND2 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 68/369 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- CROT | c.1482G>C p.M494I | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EFL1 | c.932+1G>C p.X311_splice | Splice Site (SNP) | VAF 11/53 reads (21%) | called by muse, mutect2, varscan2
- FILIP1L | c.1837A>T p.K613* (on ENST00000354552 / NM_182909.3; = p.K373* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 19/113 reads (17%) | called by muse, varscan2
- HTR3B | c.258+1G>C p.X86_splice | Splice Site (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- LGALS9 | c.640C>T p.P214S (on ENST00000395473 / NM_009587.3; = p.P182S on NM_002308.4) | Missense Mutation (SNP) | VAF 64/346 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- NABP1 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 41/215 reads (19%) | called by muse, mutect2, varscan2
- PDE1C | c.363C>G p.S121R | Missense Mutation (SNP) | VAF 32/208 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- SH3RF1 | c.2139+1del p.X713_splice | Splice Site (DEL) | VAF 6/51 reads (12%) | called by mutect2, varscan2
- SLC44A2 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 64/421 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ST14 | c.1146C>G p.F382L | Missense Mutation (SNP) | VAF 140/549 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTPA | c.233C>A p.A78E | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP40 | c.1514A>G p.E505G | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- XRN1 | c.5048del p.T1683Nfs*29 | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | called by mutect2, pindel, varscan2
- ZNF717 | c.1385A>T p.N462I | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.276); called by muse, varscan2
- ZNF792 | c.1750C>G p.H584D | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- BICRA | c.1731G>A p.P577= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1450389334; called by muse, mutect2, varscan2
- CDON | c.1725T>A p.S575= | Silent (SNP) | VAF 87/424 reads (21%) | called by muse, mutect2, varscan2
- CRYBG2 | c.3555G>T p.V1185= | Silent (SNP) | VAF 26/210 reads (12%) | called by muse, mutect2, varscan2
- HCCS | c.654C>T p.C218= | Silent (SNP) | VAF 88/388 reads (23%) | catalogued as rs775880525, COSV58239116; called by muse, mutect2, varscan2
- KRT72 | c.1140C>T p.C380= | Silent (SNP) | VAF 56/238 reads (24%) | catalogued as rs199978375, COSV53373473; called by muse, mutect2, varscan2
- LAS1L | c.1260C>T p.L420= | Silent (SNP) | VAF 80/450 reads (18%) | called by muse, mutect2, varscan2
- MTPAP | c.1515T>C p.S505= | Silent (SNP) | VAF 92/1260 reads (7%) | called by muse, mutect2
- PID1 | c.540C>T p.F180= (on ENST00000354069 / NM_001330156.1; = p.F178= on NM_017933.5) | Silent (SNP) | VAF 101/556 reads (18%) | catalogued as rs749402709, COSV62472386; called by muse, mutect2, varscan2
- PVRIG | c.774G>A p.A258= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs556053924, COSV52782082; called by muse, mutect2, varscan2
- SFTPC | c.141C>T p.V47= | Silent (SNP) | VAF 141/704 reads (20%) | catalogued as rs764818190; called by muse, mutect2, varscan2
- SNTA1 | c.777G>A p.S259= | Silent (SNP) | VAF 156/787 reads (20%) | catalogued as rs1202456575; called by muse, mutect2, varscan2
- SZT2 | c.7596T>C p.F2532= (on ENST00000634258 / NM_001365999.1; = p.F2475= on NM_015284.4) | Silent (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- ZNF71 | c.1194C>T p.I398= | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as rs1051755100, COSV60148032; called by muse, mutect2, varscan2
- DERL1 | c.154-21T>C | Intron (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- LAMA1 | c.1563+10G>A | Intron (SNP) | VAF 87/465 reads (19%) | called by muse, mutect2, varscan2
- MACF1 | c.543+11407A>G | Intron (SNP) | VAF 73/357 reads (20%) | called by muse, mutect2, varscan2
